Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A185, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A185-06A (Metastatic).

[page 1 of 2]
12/19/10 lw

ICD-0-3

Melanoma, NOS 8720/3

Site Code: GROIN, ~~SKIN~~ SKIN C44.5

years Female

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Biopsy right mid thigh - dysplastic junctional melanocytic naevus.

Core biopsy right groin node - melanoma.

1. Right groin contents (staples mark upper).
2. Tissue behind femoral nerve.
3. Wide excision melanoma right thigh.
4. Tissue from right femoral nerve region.

MACROSCOPIC DESCRIPTION

Four specimens were received.

1. "RIGHT GROIN CONTENTS STAPLES UPPER". *Portion taken from largest nodule for Tumour Banking*. An irregular piece of fatty tissue 210 x 110 x 40mm with an overlying ellipse of skin 205 x 45mm, bearing staples at the upper (superior) pole. The skin surface appears overall unremarkable. Multiple involved lymph nodes were identified, including an enlarged necrotic lymph node up to 45mm in maximum dimension.

All of lymph nodes embedded sequentially from superior to inferior.

- A. Most superior lymph node.
- B. 1 lymph node trisected. All embedded.
- C. Representative, 1 involved lymph node.
- D-E. Representative, 1 involved lymph node.
- F. 1 involved lymph node bisected all embedded.
- G-H. 1 lymph node bisected all embedded.
- J. 2 lymph nodes.
- K. Representative involved lymph node.
- L. Representative involved lymph node.

2. "TISSUE BEHIND RIGHT FEMORAL NERVE". A dark brown piece of tissue, (?lymph node) 7mm across. Embedded whole in one block.

3. "TUMOUR RIGHT THIGH". An unorientated ellipse of skin 120 x 40mm with an underlying mass of subcutaneous tissue 125 x 50 x 35mm. Fascia is present on the deep aspect. On the skin surface centrally is a crusted grey plaque 30 x 20mm, lying clear of the margins. One long margin inked blue, opposite black. Serial sectioning through the area of the crusting, shows a partially necrotic nodule centered in the subcutis (15 x 8 x 7mm, surrounded by haemorrhagic fatty tissue). The nodule lies well clear of all margins (up to 20mm from the deep margin and 17mm from the closest peripheral margin).

- A. Representative necrotic lesion showing closest peripheral (blue inked) margin, deep margin and opposite long margin trimmed.
- B. Representative necrotic lesion.
- C-E. Further blocks (remainder of necrotic nodule embedded).

[page 2 of 2]
Requested by:

MRN/Name:

Location:

Accession:

HISTOPATHOLOGY REPORT

4. "TISSUE AROUND RIGHT FEMORAL NERVE". An irregular piece of grey and haemorrhagic fibrous and fatty tissue 35 x 25 x 10mm. Cut section shows uniform fibrofatty tissue. Bisected and all embedded in two blocks (A-B).

MICROSCOPIC REPORT

1. "RIGHT GROIN CONTENTS STAPLES UPPER". Sections show metastatic melanoma in six of nine lymph nodes (6/9), and one extranodal subcutaneous deposit of melanoma with focal dermal involvement (blocks 1D and 1E). Tumour deposits consist of sheets of epithelioid pleomorphic cells with prominent central eosinophilic nucleoli, and variable dusty dark brown pigment.

2. "TISSUE BEHIND RIGHT FEMORAL NERVE". Sections show a deposit of metastatic melanoma. Lymph node tissue is not identified.

3. "TUMOUR RIGHT THIGH". The skin contains an abscess within the deep dermis and subcutis, underlying epidermal and dermal scar from the recent surgery. Residual melanoma is not identified and melanocytic lesion is not seen.

4. "TISSUE AROUND RIGHT FEMORAL NERVE". The specimen consists of skeletal muscle and adipose tissue. A 3.5mm deposit of metastatic melanoma is seen within adipose tissue. Lymph node tissue is not.

SUMMARY

1. Lymph node dissection, and skin, right groin : **METASTATIC MELANOMA IN 6 OF 9 LYMPH NODES AND AN EXTRANODAL SUBCUTANEOUS DEPOSIT.**

/

2. Soft tissue, behind femoral nerve : **METASTATIC MELANOMA.**

/

3. Skin, right thigh, wide excision : **ABSCCESS CAVITY AND SCAR.**
: **NO EVIDENCE OF MALIGNANCY.**

/

4. Soft tissue, right femoral nerve region : **METASTATIC MELANOMA.**

REPORTED BY: Dr

Source: NCI Genomic Data Commons file bcd3e8e3-7c9d-4477-bdc1-06d07afbe37e (TCGA-EE-A185.B031620A-AE3E-408C-8CBB-52E0CC56C51E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).